Surgical pathology report (de-identified scan), TCGA case TCGA-FX-A3NK, project TCGA-SARC (Sarcoma), tissue source site International Genomics Consortium, specimen TCGA-FX-A3NK-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

* Final Report *

Result type: Surgical Pathology Report
Result date:
Result status: Modified
Result title: Surgical Pathology Report
Performed by:
Verified by:
Encounter info:

Case History		☒

1/7/12

* Final Report *

Ordering Provider

Ordering Physician:

Clinical History

Gastric mass; reported GIST (no recent biopsy at 1 ; prior reactive myofibroblastic proliferation with gastric ulceration in 2000, previously reviewed at); left nephrectomy in 2000 for xanthogranulomatous inflammation

Specimen

- #1 Omental nodule
- #2 Subtotal gastrectomy
- #3 Gastric margin (stitch in margin)
- #4 Proximal stomach
- #5 Omentum

1CD-0-3
dedifferentiated liposarcoma 8858/3
Site: stomach, NOS C16.9

1/7/12

Gross Examination

#1 Labeled "omental nodule", is a 1.9 x 1.4 x 1.2 cm fragment of adipose tissue which is inked and sectioned to reveal a 0.7 cm in diameter firm, tan yellow mottled nodule. It is completely submitted in "1A,1B".

#2 Portion of stomach: Received in the fresh state is a portion of stomach roughly 25.5 cm in length (along the lesser curvature and roughly 14.5 cm in length along the lesser curvature. The specimen is oriented intraoperatively courtesy of Drs. and . Along the proximal portion of the stomach is a row of metallic sutures roughly 16 cm in length. It is understood that the most cephalad portion of the specimen represents the area of the proximal gastric resection margin. The serosal surface contains scattered adhesions but is otherwise unremarkable. Near the area of the cephalad sutures is a mucosal based polypoid tumor roughly 8.5 x 5.5 x 5.0 cm. The polyp is attached to the underlying mucosa by a thin band of soft pink tissue roughly 2.5 cm in length x 2.0 cm width and 0.5 cm in thickness. Roughly 4 cm distal to the large polyp is a smaller sessile polypoid area roughly 1.2 x 1.0 cm in diameter and averaging 0.3 cm in thickness. A small amount of perigastric adipose tissue is present along the greater curvature. A few small lymph node candidates are identified. The specimen is re-evaluated following overnight fixation in

Printed by:
Printed on:

Page 1 of 3
(Continued)

[page 2 of 3]
Surgical Pathology Report

* Final Report *

Sampled in sixteen cassettes. Block summary: "A", distal (duodenal resection margin) perpendicular resection; "B", proximal gastric resection margin (tangential section); "C", stalk of mucosal polypoid tumor; "D-H", mucosal polypoid tumor; "I,J", gastric wall adjacent to polyp; "K,L", distal polypoid area; "M", random gastric section; "N-P", perigastric lymph node candidates; "Q-P Additional perigastric lymph node candidates

#3 Labeled "gastric margin, stitch in margin", is a 2.5 x 2.5 x 1.7 cm fragment of gastric mucosa. Half of the fragment has underlying gastric wall. There is a 3.0 cm long staple line which is removed and retained in formalin. The underlying mucosa is representative perpendicular sections "3A,3B".

#4 Labeled with the patient's name and "proximal stomach", is a 7.0 x 3.5 x 3.0 cm segment of stomach which has been previously partially opened. There is a 3.4 cm long staple lined and 7.0 cm long staple line. The remainder of the specimen is opened. There are no mucosal lesions identified. There are diffuse dark brown areas. Dr. has reviewed the gross pathology. Block summary: "4A,4B", representative sections abutting each staple line; "4C-4F", representative central sections.

#5 Labeled with the patient's name and omentum, is a 21.0 x 11.0 x up to 3.0 cm fragment of omentum which is sectioned in 0.4 cm increments. There are no nodules identified. On the surface there is a light tan nodule 0.2 cm in greatest dimension. Representative sections are submitted in "5A,5B", the described nodule is submitted in "5A".

Microscopic Examination

#1-5 Microscopic examination performed. Sections from the large pedunculated gastric polyp show a bland spindle cell proliferation with entrapped collagen fibers and scattered foci of eosinophils, lymphocytes and plasma cells. The process extends to the mucosal surface and envelopes benign gastric glands. There is no necrosis and there are no atypical mitotic figures. Immunostains are evaluated. The spindle cells show the following findings: SMA(+), c-kit(-), CD34(-), S-100(-), CD68(patchy +).

Comment

The stomach resection contains two polypoid lesions. One is a large pedunculated polyp comprising a bland spindle cell process similar to that seen in the prior gastric resection in , which was reviewed at the . The second polyp is sessile and contains a less cellular fibroblastic proliferation. The pertinent slides from the current case will be sent to for consultation. Upon receipt of the consultant's diagnosis, an amended report will be issued. Drs. and have also reviewed the case.

Part #2 was reviewed by Dr.

at

(

. The

Printed by:
Printed on:

Page 2 of 3
(Continued)

[page 3 of 3]
Surgical Pathology Report

* Final Report *

smaller, sessile gastric polyp consists of an atypical lipomatous proliferation, consistent with a well-differentiated liposarcoma. The larger, pedunculated polyp contains a bland spindle cell proliferation. Taken in the context of the lipomatous tumor, the spindle cell process is consistent with de-differentiated liposarcoma. The report indicates that FISH studies show CPM gene amplification, further supporting the diagnosis of liposarcoma. The final diagnosis was phoned to the office of Dr. on . The report is amended to include the external consultant's diagnosis.

This report is amended to correct the date entered for the Amended Final Diagnosis from . The diagnosis itself is not changed.

Signature Line

Signed by:
ELECTRONIC SIGNATURE

Final Diagnosis

- #1 SOFT TISSUE, OMENTUM, EXCISION: FAT NECROSIS.
- #2 STOMACH, SUBTOTAL GASTRECTOMY: PENDING EXTERNAL CONSULTATION. (SEE COMMENT)
- #3 STOMACH MARGIN, FURTHER EXCISION: SEGMENT OF BENIGN STOMACH.
- #4 STOMACH, PROXIMAL, RESECTION: SEGMENT OF BENIGN STOMACH.
- #5 SOFT TISSUE, OMENTUM, EXCISION: BENIGN ADIPOSE TISSUE.

AMENDED FINAL DIAGNOSIS:

- #2 STOMACH, SUBTOTAL GASTRECTOMY:
LIPOSARCOMA WITH DE-DIFFERENTIATION, FORMING TWO POLYPOID MASSES
WITHIN
THE STOMACH (8.5 CM AND 1.2 CM).
MARGINS ARE NEGATIVE. (SEE COMMENT OF

Printed by:
Printed on:

Page 3 of 3
(End of Report)

Source: NCI Genomic Data Commons file 85bd66c9-e87d-47f9-9794-5acc30d2b887 (TCGA-FX-A3NK.5749AEB5-0BED-43BC-8CDA-30441B0FFE00.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).